Somatic mutation profile of cancer-model specimen HCM-SANG-0314-C15-85A (3D Organoid; aliquot HCM-SANG-0314-C15-85A-01D-A79N-36), derived from the primary tumor of HCMI case HCM-SANG-0314-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0314-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f00f0e7f-2971-45fc-a50c-fb0d38ec101a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0314-C15-10A (Blood Derived Normal), aliquot HCM-SANG-0314-C15-10A-01D-A79N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9f83bb2-72e7-477c-bd37-a46e5297e046

The open-access MAF lists 282 somatic variants for this specimen: 212 protein-altering or splice-affecting, 60 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 189, Silent 60, Nonsense Mutation 10, Intron 5, Frame Shift Ins 3, 3'UTR 3, Frame Shift Del 3, Splice Region 3, In Frame Del 2, IGR 1, Nonstop Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 237/237 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985033810, CM056069, CM070298, COSV52661058, COSV52724858, COSV52839584; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.1795C>T p.R599W | Missense Mutation (SNP) | VAF 155/351 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs762026626, COSV100252717, COSV100253108; called by muse, mutect2, varscan2
- ABCC8 | c.1943G>A p.R648H | Missense Mutation (SNP) | VAF 152/573 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs773168707; called by muse, mutect2, varscan2
- ADGRE2 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 17/382 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59694037; called by muse, mutect2
- AMPH | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 84/491 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.742); catalogued as rs1396277693; called by muse, mutect2, varscan2
- ANK2 | c.6677G>C p.S2226T | Missense Mutation (SNP) | VAF 36/312 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); catalogued as rs766360388; called by muse, mutect2, varscan2
- APOB | c.8572G>T p.A2858S | Missense Mutation (SNP) | VAF 23/567 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as rs1354286379; called by muse, mutect2
- ARID2 | c.551C>G p.S184* | Nonsense Mutation (SNP) | VAF 251/465 reads (54%) | catalogued as COSV57600529, COSV57604556; called by muse, mutect2, varscan2
- ARID5A | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 288/610 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs368122000; called by muse, mutect2, varscan2
- ASCC3 | c.3745G>A p.E1249K | Missense Mutation (SNP) | VAF 34/262 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.444); catalogued as COSV100226391; called by muse, mutect2, varscan2
- ATP1A3 | c.1174G>A p.A392T (on ENST00000545399 / NM_001256214.2; = p.A379T on NM_152296.5) | Missense Mutation (SNP) | VAF 199/650 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.675); catalogued as COSV57488799; called by muse, mutect2, varscan2
- C8B | c.413T>G p.L138R | Missense Mutation (SNP) | VAF 83/264 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs955479183, COSV100980703, COSV64777175; called by muse, mutect2, varscan2
- C9orf16 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 398/715 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs760211969; called by muse, mutect2, varscan2
- CAPZA2 | c.585G>T p.Q195H | Missense Mutation (SNP) | VAF 33/371 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.343); catalogued as COSV100753780; called by muse, mutect2
- CCKAR | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 251/471 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55161754; called by muse, mutect2, varscan2
- CDH9 | c.487T>G p.L163V | Missense Mutation (SNP) | VAF 93/210 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV50253829, COSV99145286, COSV99163241; called by muse, mutect2, varscan2
- CLSTN3 | c.644A>C p.K215T | Missense Mutation (SNP) | VAF 17/551 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0.101); catalogued as rs1436187000; called by muse, mutect2
- CNTLN | c.2813A>C p.K938T | Missense Mutation (SNP) | VAF 115/235 reads (49%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV52093458, COSV99262418; called by muse, mutect2, varscan2
- COL4A1 | c.4832C>T p.A1611V | Missense Mutation (SNP) | VAF 520/855 reads (61%) | SIFT tolerated (0.2); PolyPhen benign (0.067); catalogued as rs775233741, COSV65423218, COSV65434312; called by muse, mutect2, varscan2
- CPA3 | c.494G>C p.R165T | Missense Mutation (SNP) | VAF 110/172 reads (64%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV56047681; called by muse, mutect2, varscan2
- CPB2 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 70/590 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs745915460, COSV51675401, COSV51676445; called by muse, mutect2, varscan2
- CPXM2 | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 163/484 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); catalogued as rs770522746, COSV53860400; called by muse, mutect2, varscan2
- CREBZF | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 161/476 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1415613126; called by muse, mutect2, varscan2
- CYP26C1 | c.1319C>A p.S440Y | Missense Mutation (SNP) | VAF 42/840 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs759195045; called by muse, mutect2
- DMD | c.4088A>C p.K1363T | Missense Mutation (SNP) | VAF 12/211 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.059); catalogued as COSV63732568, COSV63756777; called by muse, mutect2
- DNTTIP2 | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 179/239 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs756513922, COSV63283920; called by muse, mutect2, varscan2
- DOCK3 | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 151/395 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); catalogued as rs756421617, COSV56539986; called by muse, mutect2, varscan2
- ELAC2 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 68/198 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs1273371887; called by muse, varscan2
- EMC1 | c.2690C>T p.P897L | Missense Mutation (SNP) | VAF 96/308 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs146583625; called by muse, mutect2, varscan2
- ERICH3 | c.130G>C p.G44R | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58614605; called by muse, mutect2, varscan2
- EXT1 | c.1836G>C p.W612C | Missense Mutation (SNP) | VAF 447/682 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as CM099181, COSV65478653; called by muse, mutect2, varscan2
- FAM81A | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 146/359 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55680254; called by muse, mutect2
- GCFC2 | c.2216G>C p.R739T | Missense Mutation (SNP) | VAF 13/222 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs950086376; called by muse, mutect2
- GRIK2 | c.2503G>C p.V835L | Missense Mutation (SNP) | VAF 18/468 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV99053606; called by muse, mutect2
- HAPLN3 | c.290C>A p.P97Q | Missense Mutation (SNP) | VAF 62/866 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.026); catalogued as COSV100613665; called by muse, mutect2
- HMBOX1 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 174/174 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55066470; called by muse, mutect2, varscan2
- IGHE | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 251/502 reads (50%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.877); catalogued as rs782083953; called by muse, mutect2, varscan2
- IL12B | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 292/438 reads (67%) | SIFT tolerated (0.29); PolyPhen benign (0.071); catalogued as COSV104370863; called by muse, varscan2
- ITIH2 | c.1063A>T p.I355F | Missense Mutation (SNP) | VAF 97/517 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV64435744; called by muse, mutect2, varscan2
- KRT34 | c.1168C>T p.R390W | Missense Mutation (SNP) | VAF 282/686 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as rs200232759; called by muse, mutect2, varscan2
- KRT82 | c.455G>A p.W152* | Nonsense Mutation (SNP) | VAF 38/714 reads (5%) | catalogued as rs745512803; called by muse, mutect2
- KSR2 | c.1784C>T p.P595L | Missense Mutation (SNP) | VAF 267/586 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs747557790, COSV56672047; called by muse, varscan2
- LMX1A | c.1128G>C p.Q376H | Missense Mutation (SNP) | VAF 19/374 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV54220597; called by muse, mutect2
- LUZP2 | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 40/516 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs768991269; called by muse, mutect2
- MDH1B | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 194/458 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs779426389, COSV65588397; called by muse, mutect2, varscan2
- MEPE | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 209/433 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755462303; called by muse, mutect2, varscan2
- MLPH | c.769C>T p.H257Y | Missense Mutation (SNP) | VAF 28/750 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.308); catalogued as rs1176326809, COSV52821163, COSV99222272; called by muse, mutect2
- MYH15 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 64/183 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as rs201981854; called by muse, varscan2
- MYO15A | c.2200G>A p.D734N | Missense Mutation (SNP) | VAF 103/452 reads (23%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs1435631082; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEB | c.13763G>A p.R4588Q | Missense Mutation (SNP) | VAF 98/190 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs575958060, COSV50890065; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEU1 | c.1021C>T p.R341* | Nonsense Mutation (SNP) | VAF 26/528 reads (5%) | catalogued as rs751458617, CM040099, CM113390, COSV99998821; called by muse, mutect2
- OASL | c.974G>A p.R325K | Missense Mutation (SNP) | VAF 19/611 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.718); catalogued as rs1175223095; called by muse, mutect2
- OR51G1 | c.349C>G p.L117V | Missense Mutation (SNP) | VAF 264/395 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100429398; called by muse, mutect2, varscan2
- PABPC4L | c.1056G>T p.M352I | Missense Mutation (SNP) | VAF 172/339 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV69931176, COSV99081465; called by muse, mutect2, varscan2
- PCDH11Y | c.2988A>C p.Q996H (on ENST00000400457 / NM_032973.2; = p.Q985H on NM_032971.3) | Missense Mutation (SNP) | VAF 46/348 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99292334; called by muse, mutect2, varscan2
- PCDH15 | c.538G>C p.D180H | Missense Mutation (SNP) | VAF 18/394 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57378887; called by muse, mutect2
- PCDH9 | c.3714A>C p.*1238Yext*26 (on ENST00000377865 / NM_203487.3; = p.*1204Yext*26 on NM_020403.5 and 1 other RefSeq transcript) | Nonstop Mutation (SNP) | VAF 41/473 reads (9%) | catalogued as COSV60531117, COSV60535317, COSV60559707; called by muse, mutect2
- PCDHA3 | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 287/288 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65364216; called by muse, mutect2, varscan2
- PCDHB13 | c.2036C>T p.T679I | Missense Mutation (SNP) | VAF 65/578 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs376242901, COSV99507936; called by muse, mutect2, varscan2
- PCDHB3 | c.2053T>G p.L685V | Missense Mutation (SNP) | VAF 30/716 reads (4%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.005); catalogued as COSV50569542; called by muse, mutect2
- PCDHB6 | c.1411G>A p.V471I | Missense Mutation (SNP) | VAF 556/581 reads (96%) | SIFT tolerated (0.46); PolyPhen benign (0.058); catalogued as COSV50699885; called by muse, mutect2, varscan2
- PLA2G7 | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 152/320 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as rs767724546, COSV51258335; called by muse, mutect2, varscan2
- PLXDC2 | c.77A>T p.Q26L | Missense Mutation (SNP) | VAF 52/668 reads (8%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as COSV65924639; called by muse, mutect2
- PPP1R42 | c.688G>T p.E230* | Nonsense Mutation (SNP) | VAF 104/309 reads (34%) | catalogued as rs909819876; called by muse, mutect2, varscan2
- PTPN23 | c.3529G>A p.E1177K | Missense Mutation (SNP) | VAF 65/546 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as rs775553662; called by muse, mutect2, varscan2
- PTPRT | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 203/785 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV61986719; called by muse, mutect2, varscan2
- RFPL4A | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 110/926 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.116); catalogued as rs1411535138, COSV70455742; called by muse, varscan2
- RFPL4AL1 | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 22/221 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.219); catalogued as rs1301570110; called by muse, mutect2, varscan2
- RIMS2 | c.3164G>A p.R1055H (on ENST00000666250 / NM_001348490.2; = p.R863H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 400/605 reads (66%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as rs199562210, COSV51667384; called by muse, mutect2, varscan2
- RNF217 | c.1205G>A p.G402E (on ENST00000521654 / NM_001286398.2; = p.G110E on NM_152553.5) | Missense Mutation (SNP) | VAF 15/554 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as COSV51577615; called by muse, mutect2
- RSPO2 | c.99T>G p.S33R | Missense Mutation (SNP) | VAF 31/495 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.191); catalogued as COSV52641791, COSV99410716; called by muse, mutect2
- SDK1 | c.4487G>A p.R1496Q | Missense Mutation (SNP) | VAF 536/914 reads (59%) | SIFT tolerated (0.61); PolyPhen benign (0.011); catalogued as rs141114121; called by muse, mutect2, varscan2
- SEMA5A | c.1279G>A p.G427R | Missense Mutation (SNP) | VAF 75/190 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751530635, COSV66784394; called by muse, mutect2, varscan2
- SFMBT2 | c.2065G>A p.A689T | Missense Mutation (SNP) | VAF 242/506 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs748712257, COSV62805508; called by muse, mutect2, varscan2
- SLC6A1 | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 185/311 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs767142926; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNTG1 | c.295C>G p.L99V | Missense Mutation (SNP) | VAF 35/513 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1440793668; called by muse, mutect2
- SORCS3 | c.1132G>C p.E378Q | Missense Mutation (SNP) | VAF 143/344 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV63806753, COSV99056408; called by muse, mutect2, varscan2
- SP3 | c.72_83del p.G26_G29del | In Frame Del (DEL) | VAF 222/634 reads (35%) | catalogued as rs759652858; called by mutect2, varscan2
- SPAG6 | c.1458G>T p.V486= | Splice Region (SNP) | VAF 42/195 reads (22%) | catalogued as rs748911844; called by muse, mutect2, varscan2
- SYNE1 | c.18811G>A p.A6271T (on ENST00000367255 / NM_182961.4; = p.A6200T on NM_033071.3) | Missense Mutation (SNP) | VAF 30/362 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV54991945; called by muse, mutect2
- TEKT4 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 364/796 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs782558219, COSV54626009; called by muse, mutect2, varscan2
- TLE3 | c.881G>A p.S294N | Missense Mutation (SNP) | VAF 26/580 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.056); catalogued as rs1289937765; called by muse, mutect2
- TMEM266 | c.1151C>T p.A384V | Missense Mutation (SNP) | VAF 351/738 reads (48%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.02); catalogued as rs763774429; called by muse, mutect2, varscan2
- TSNAXIP1 | c.989_991del p.V330del | In Frame Del (DEL) | VAF 119/322 reads (37%) | catalogued as rs764966774; called by pindel, varscan2
- UNC80 | c.4345G>A p.A1449T | Missense Mutation (SNP) | VAF 166/356 reads (47%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs553977942; called by muse, mutect2, varscan2
- XPR1 | c.1111C>G p.R371G | Missense Mutation (SNP) | VAF 33/307 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760728379, COSV62558965; called by mutect2, varscan2
- ZFHX4 | c.9839G>T p.G3280V | Missense Mutation (SNP) | VAF 449/682 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV50701146, COSV51468983; called by muse, mutect2, varscan2
- ABCC9 | c.2230A>C p.T744P | Missense Mutation (SNP) | VAF 131/339 reads (39%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- ADAMTS5 | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 85/760 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADRA1A | c.136C>A p.L46I | Missense Mutation (SNP) | VAF 25/292 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- AHNAK2 | c.14806C>T p.P4936S | Missense Mutation (SNP) | VAF 22/735 reads (3%) | SIFT tolerated (0.64); PolyPhen benign (0.316); called by muse, mutect2
- AHNAK2 | c.14489A>C p.D4830A | Missense Mutation (SNP) | VAF 19/522 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.015); called by muse, mutect2
- ARHGAP4 | c.2456G>A p.G819E | Missense Mutation (SNP) | VAF 18/500 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.068); called by muse, mutect2
- ARHGAP5 | c.1733A>T p.Q578L | Missense Mutation (SNP) | VAF 14/400 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.122); called by muse, mutect2
- ARHGEF15 | c.1566C>A p.S522R | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.103); called by muse, mutect2
- ARHGEF28 | c.4406A>T p.E1469V | Missense Mutation (SNP) | VAF 23/400 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.314); called by muse, mutect2
- ARID1A | c.1245T>A p.H415Q | Missense Mutation (SNP) | VAF 32/498 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.69); called by muse, mutect2
- ARID1A | c.1246G>T p.G416W | Missense Mutation (SNP) | VAF 32/498 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ARID2 | c.5371_5372del p.K1791Efs*3 | Frame Shift Del (DEL) | VAF 99/273 reads (36%) | called by mutect2, pindel, varscan2
- ARMC4 | c.1483G>T p.G495C | Missense Mutation (SNP) | VAF 47/531 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.623); called by muse, mutect2
- ASIC5 | c.418C>T p.H140Y | Missense Mutation (SNP) | VAF 152/440 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ATMIN | c.444G>C p.Q148H | Missense Mutation (SNP) | VAF 147/268 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATXN2 | c.3202C>T p.P1068S (on ENST00000550104; = p.P908S on NM_002973.4) | Missense Mutation (SNP) | VAF 48/515 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ATXN3 | c.144G>T p.M48I | Missense Mutation (SNP) | VAF 235/465 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.34); called by mutect2, varscan2
- BACH2 | c.1577A>G p.Y526C | Missense Mutation (SNP) | VAF 128/536 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BCL2 | c.439A>T p.I147F | Missense Mutation (SNP) | VAF 45/964 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BRPF3 | c.2000A>T p.K667M | Missense Mutation (SNP) | VAF 26/664 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.495); called by muse, mutect2
- C2orf16 | c.4108G>A p.V1370M | Missense Mutation (SNP) | VAF 168/354 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CCDC88B | c.2538G>T p.M846I | Missense Mutation (SNP) | VAF 120/506 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CD1D | c.727C>A p.Q243K | Missense Mutation (SNP) | VAF 32/708 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2
- CD8A | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 32/670 reads (5%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.75); called by muse, mutect2
- CEP192 | c.1297G>A p.D433N | Missense Mutation (SNP) | VAF 16/506 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.062); called by muse, mutect2
- CEP57 | c.927del p.V310Sfs*4 | Frame Shift Del (DEL) | VAF 54/239 reads (23%) | called by mutect2, pindel, varscan2
- CHIA | c.267G>C p.Q89H | Missense Mutation (SNP) | VAF 76/293 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- CHST15 | c.1013A>T p.K338M | Missense Mutation (SNP) | VAF 12/386 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.294); called by muse, mutect2
- COG5 | c.2103C>G p.F701L (on ENST00000347053 / NM_001379512.1; = p.F722L on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/491 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.006); called by muse, mutect2
- COPS8 | c.230T>A p.V77E | Missense Mutation (SNP) | VAF 36/462 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- CORO1A | c.1215G>C p.R405S | Missense Mutation (SNP) | VAF 175/430 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CRYBB2 | c.304G>T p.V102L | Missense Mutation (SNP) | VAF 61/297 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CTTN | c.117G>A p.W39* | Nonsense Mutation (SNP) | VAF 38/374 reads (10%) | called by muse, mutect2
- DENND2C | c.1088A>C p.K363T | Missense Mutation (SNP) | VAF 89/262 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DHX9 | c.3590G>T p.G1197V | Missense Mutation (SNP) | VAF 46/421 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- DNAI2 | c.1750G>T p.V584L | Missense Mutation (SNP) | VAF 9/218 reads (4%) | SIFT tolerated (0.83); PolyPhen benign (0.001); called by muse, mutect2
- DPYSL5 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 60/669 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ELAVL2 | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 30/412 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- EPHA6 | c.1201A>C p.T401P | Missense Mutation (SNP) | VAF 24/430 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); called by muse, mutect2
- EXOSC5 | c.60C>G p.S20R | Missense Mutation (SNP) | VAF 58/1042 reads (6%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2
- FAM117B | c.695A>T p.H232L | Missense Mutation (SNP) | VAF 34/520 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.311); called by muse, mutect2
- FAM171B | c.2287A>C p.I763L | Missense Mutation (SNP) | VAF 179/398 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- FLRT2 | c.455A>G p.D152G | Missense Mutation (SNP) | VAF 83/333 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- FN1 | c.5135A>G p.Q1712R | Missense Mutation (SNP) | VAF 59/356 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- GOLGA6L2 | c.1187A>C p.E396A | Missense Mutation (SNP) | VAF 54/1012 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.486); called by muse, mutect2
- GUCA1C | c.583T>C p.S195P | Missense Mutation (SNP) | VAF 42/450 reads (9%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.188); called by muse, mutect2
- GUCY1B1 | c.37G>T p.V13L | Missense Mutation (SNP) | VAF 104/473 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ICA1 | c.891G>T p.Q297H | Missense Mutation (SNP) | VAF 31/656 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.153); called by muse, mutect2
- IQCM | c.1137T>G p.I379M | Missense Mutation (SNP) | VAF 89/339 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ITCH | c.1462T>C p.F488L (on ENST00000262650 / NM_001257137.3; = p.F447L on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/811 reads (3%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.823); called by muse, mutect2
- IZUMO3 | c.431T>C p.L144P (on ENST00000543880 / NM_001365008.2; = p.L138P on NM_001271706.1) | Missense Mutation (SNP) | VAF 17/426 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2
- KALRN | c.8366A>G p.E2789G (on ENST00000360013 / NM_001024660.4; = p.E1092G on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/345 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- KIF4A | c.2444C>G p.S815C | Missense Mutation (SNP) | VAF 10/276 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- KLHL2 | c.331dup p.I111Nfs*2 | Frame Shift Ins (INS) | VAF 47/346 reads (14%) | called by mutect2, pindel, varscan2
- LARP6 | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 69/540 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- LCT | c.4165G>T p.A1389S | Missense Mutation (SNP) | VAF 16/289 reads (6%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.515); called by muse, mutect2
- LDB2 | c.916A>C p.T306P | Missense Mutation (SNP) | VAF 26/462 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, mutect2
- LILRB2 | c.369A>C p.K123N | Missense Mutation (SNP) | VAF 76/648 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by mutect2, varscan2
- LINGO4 | c.892C>A p.P298T | Missense Mutation (SNP) | VAF 34/696 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2
- LOXHD1 | c.4516T>A p.F1506I | Missense Mutation (SNP) | VAF 164/376 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP2 | c.2144C>A p.S715Y | Missense Mutation (SNP) | VAF 25/337 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2
- LRRIQ1 | c.2657A>C p.Q886P | Missense Mutation (SNP) | VAF 33/291 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- LSG1 | c.266C>A p.T89N | Missense Mutation (SNP) | VAF 194/336 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- LYPLA1 | c.98C>G p.T33S | Missense Mutation (SNP) | VAF 139/433 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- MCM3AP | c.4885T>G p.C1629G | Missense Mutation (SNP) | VAF 46/696 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- MMUT | c.2126A>T p.D709V | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MOS | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 45/662 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2
- MYEF2 | c.1531G>A p.G511R | Missense Mutation (SNP) | VAF 14/530 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYOD1 | c.633G>A p.M211I | Missense Mutation (SNP) | VAF 140/441 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- NDST4 | c.1672C>A p.H558N | Missense Mutation (SNP) | VAF 14/386 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- NLRP5 | c.740A>T p.E247V | Missense Mutation (SNP) | VAF 49/853 reads (6%) | SIFT tolerated (0.94); PolyPhen benign (0.003); called by muse, mutect2
- NOX4 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 13/268 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.326); called by muse, mutect2
- NOX5 | c.835T>G p.F279V | Missense Mutation (SNP) | VAF 26/618 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); called by muse, mutect2
- NR3C1 | c.302del p.D101Afs*19 | Frame Shift Del (DEL) | VAF 58/310 reads (19%) | called by mutect2, pindel, varscan2
- NUGGC | c.1558G>T p.G520W | Missense Mutation (SNP) | VAF 16/316 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR1Q1 | c.280T>A p.Y94N | Missense Mutation (SNP) | VAF 58/634 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2
- OR5B12 | c.649T>G p.L217V | Missense Mutation (SNP) | VAF 11/299 reads (4%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.074); called by muse, mutect2
- OSBPL2 | c.316C>T p.R106W (on ENST00000313733 / NM_144498.4; = p.R94W on NM_014835.4) | Missense Mutation (SNP) | VAF 163/917 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OSBPL8 | c.464T>G p.L155* | Nonsense Mutation (SNP) | VAF 160/338 reads (47%) | called by muse, mutect2, varscan2
- OVCH1 | c.1896C>A p.D632E | Missense Mutation (SNP) | VAF 23/538 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.155); called by muse, mutect2
- PAK5 | c.1247G>T p.W416L | Missense Mutation (SNP) | VAF 52/1087 reads (5%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.468); called by muse, mutect2
- PEX1 | c.1150C>G p.L384V | Missense Mutation (SNP) | VAF 38/492 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- PIEZO2 | c.5378A>T p.E1793V | Missense Mutation (SNP) | VAF 38/826 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2
- PKD1L1 | c.632G>A p.G211E | Missense Mutation (SNP) | VAF 42/750 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.099); called by muse, mutect2
- PLEKHG2 | c.2144G>A p.G715E | Missense Mutation (SNP) | VAF 24/928 reads (3%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.642); called by muse, mutect2
- PLEKHG2 | c.3178G>A p.G1060S | Missense Mutation (SNP) | VAF 25/906 reads (3%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.037); called by muse, mutect2
- POP1 | c.2081A>C p.N694T | Missense Mutation (SNP) | VAF 131/389 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PREX1 | c.973T>C p.Y325H | Missense Mutation (SNP) | VAF 29/855 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PROX2 | c.59A>G p.E20G | Missense Mutation (SNP) | VAF 44/425 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- PTCHD3 | c.2192A>T p.N731I | Missense Mutation (SNP) | VAF 216/455 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PTPRQ | c.1801G>T p.V601F (on ENST00000616559; = p.V559F on NM_001145026.2) | Missense Mutation (SNP) | VAF 18/352 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.027); called by muse, mutect2
- RELN | c.5411T>G p.L1804R | Missense Mutation (SNP) | VAF 86/824 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SAMSN1 | c.233A>G p.K78R | Missense Mutation (SNP) | VAF 16/466 reads (3%) | SIFT tolerated (0.75); PolyPhen benign (0.021); called by muse, mutect2
- SETBP1 | c.1097A>G p.E366G | Missense Mutation (SNP) | VAF 185/395 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- SIGLEC1 | c.2887C>T p.Q963* | Nonsense Mutation (SNP) | VAF 57/1054 reads (5%) | called by muse, mutect2
- SLC9A9 | c.589G>T p.G197* | Nonsense Mutation (SNP) | VAF 14/393 reads (4%) | called by muse, mutect2
- SMG5 | c.545C>A p.S182Y | Missense Mutation (SNP) | VAF 14/342 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.026); called by muse, mutect2
- SMIM33 | c.102G>A p.W34* | Nonsense Mutation (SNP) | VAF 12/282 reads (4%) | called by muse, mutect2
- SNRPB2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 14/415 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.149); called by muse, mutect2
- STAB1 | c.1827G>T p.E609D | Missense Mutation (SNP) | VAF 22/294 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2
- STOML3 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 356/579 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TENM3 | c.3079_3080insG p.I1027Sfs*4 | Frame Shift Ins (INS) | VAF 185/477 reads (39%) | called by mutect2, pindel, varscan2
- TENM4 | c.1103T>A p.L368Q | Missense Mutation (SNP) | VAF 98/308 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMEM229A | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 385/662 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TRBV20OR9-2 | c.6G>C p.E2D | Missense Mutation (SNP) | VAF 229/471 reads (49%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- TRIM67 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 250/845 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TTC13 | c.2392G>T p.V798F | Missense Mutation (SNP) | VAF 42/317 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- TWNK | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 48/523 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, mutect2
- TYK2 | c.1368G>A p.L456= | Splice Region (SNP) | VAF 21/206 reads (10%) | called by muse, mutect2, varscan2
- UBR5 | c.7685A>G p.K2562R | Missense Mutation (SNP) | VAF 198/326 reads (61%) | SIFT tolerated (0.54); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- USP42 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 200/477 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- VILL | c.110A>T p.E37V | Missense Mutation (SNP) | VAF 24/421 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- VPS33A | c.1167C>G p.V389= | Splice Region (SNP) | VAF 24/410 reads (6%) | called by muse, mutect2
- WDR6 | c.992G>A p.G331E | Missense Mutation (SNP) | VAF 49/427 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- WHAMM | c.1316A>G p.E439G | Missense Mutation (SNP) | VAF 13/330 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- WHAMM | c.1317G>T p.E439D | Missense Mutation (SNP) | VAF 13/332 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2
- WWC2 | c.1885G>T p.E629* | Nonsense Mutation (SNP) | VAF 14/258 reads (5%) | called by muse, mutect2
- XPR1 | c.1117dup p.W373Lfs*4 | Frame Shift Ins (INS) | VAF 35/340 reads (10%) | called by mutect2, pindel, varscan2
- YLPM1 | c.3296G>A p.G1099E | Missense Mutation (SNP) | VAF 29/654 reads (4%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.187); called by muse, mutect2
- ZFR2 | c.2439G>A p.M813I | Missense Mutation (SNP) | VAF 71/298 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- ZNF225 | c.1496T>G p.L499R | Missense Mutation (SNP) | VAF 23/740 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF292 | c.1046G>C p.C349S | Missense Mutation (SNP) | VAF 74/360 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF382 | c.875A>G p.E292G | Missense Mutation (SNP) | VAF 77/621 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF578 | c.1115A>T p.K372M | Missense Mutation (SNP) | VAF 30/526 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ZNFX1 | c.5041G>C p.D1681H | Missense Mutation (SNP) | VAF 26/908 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.243); called by muse, mutect2
- ADAMTS13 | c.4176G>A p.E1392= | Silent (SNP) | VAF 37/742 reads (5%) | catalogued as rs782213683; called by muse, mutect2
- AMER2 | c.549G>A p.A183= | Silent (SNP) | VAF 138/1512 reads (9%) | catalogued as rs776231930; called by muse, mutect2
- ANO3 | c.1788T>G p.S596= | Silent (SNP) | VAF 14/420 reads (3%) | called by muse, mutect2
- ANOS1 | c.1932G>A p.P644= | Silent (SNP) | VAF 315/315 reads (100%) | catalogued as rs199652310; ClinVar: likely benign; called by muse, mutect2, varscan2
- AOC3 | c.1251G>A p.L417= | Silent (SNP) | VAF 67/692 reads (10%) | called by muse, mutect2
- ARHGAP42 | c.2193A>G p.K731= | Silent (SNP) | VAF 104/328 reads (32%) | called by muse, mutect2
- ATAD3C | c.285T>A p.T95= | Silent (SNP) | VAF 40/752 reads (5%) | called by muse, mutect2
- CNTN1 | c.744C>T p.F248= | Silent (SNP) | VAF 137/307 reads (45%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.3207C>T p.S1069= | Silent (SNP) | VAF 24/897 reads (3%) | called by muse, mutect2
- COBL | c.2367G>A p.R789= | Silent (SNP) | VAF 44/1025 reads (4%) | catalogued as COSV99472312; called by muse, mutect2
- COL5A1 | c.1074C>T p.G358= | Silent (SNP) | VAF 295/549 reads (54%) | catalogued as rs561440698, COSV65670739; ClinVar: likely benign; called by muse, mutect2, varscan2
- CREM | c.207G>A p.Q69= | Silent (SNP) | VAF 22/551 reads (4%) | called by muse, mutect2
- DACT1 | c.1209C>T p.G403= | Silent (SNP) | VAF 208/461 reads (45%) | catalogued as rs1174468297; called by muse, mutect2, varscan2
- DHX9 | c.3591A>T p.G1197= | Silent (SNP) | VAF 48/425 reads (11%) | called by muse, mutect2, varscan2
- ERVFRD-1 | c.1611C>A p.P537= | Silent (SNP) | VAF 32/295 reads (11%) | called by muse, varscan2
- EVI5L | c.2040G>A p.L680= | Silent (SNP) | VAF 46/403 reads (11%) | called by muse, mutect2, varscan2
- FAM120A | c.1800G>C p.L600= | Silent (SNP) | VAF 262/449 reads (58%) | called by muse, mutect2, varscan2
- FAM43B | c.249G>C p.L83= | Silent (SNP) | VAF 18/618 reads (3%) | called by muse, mutect2
- FBXO15 | c.216G>T p.G72= | Silent (SNP) | VAF 37/433 reads (9%) | called by muse, mutect2
- FNDC3A | c.483A>G p.G161= (on ENST00000492622 / NM_001079673.2; = p.G105= on NM_014923.5) | Silent (SNP) | VAF 20/564 reads (4%) | called by muse, mutect2
- FRMPD2 | c.1242T>A p.P414= | Silent (SNP) | VAF 21/462 reads (5%) | called by muse, mutect2
- FUS | c.141T>C p.T47= | Silent (SNP) | VAF 41/432 reads (9%) | called by muse, mutect2, varscan2
- FUT9 | c.915C>T p.V305= | Silent (SNP) | VAF 50/294 reads (17%) | catalogued as rs775747797; called by muse, mutect2, varscan2
- GOLGA3 | c.843G>A p.A281= | Silent (SNP) | VAF 254/619 reads (41%) | catalogued as rs1240328220, COSV52640767; called by muse, mutect2, varscan2
- GPR158 | c.1488C>T p.Y496= | Silent (SNP) | VAF 181/380 reads (48%) | catalogued as rs150342987; called by muse, mutect2, varscan2
- GUCA1C | c.582C>A p.S194= | Silent (SNP) | VAF 42/450 reads (9%) | catalogued as rs1200680455; called by muse, mutect2
- HHATL | c.1494G>A p.Q498= | Silent (SNP) | VAF 27/403 reads (7%) | called by muse, mutect2
- IMMT | c.666G>A p.K222= | Silent (SNP) | VAF 12/397 reads (3%) | called by muse, mutect2
- INAVA | c.405G>A p.E135= | Silent (SNP) | VAF 22/576 reads (4%) | called by muse, mutect2
- MARF1 | c.5145C>T p.P1715= | Silent (SNP) | VAF 86/504 reads (17%) | catalogued as rs778124218, COSV60025055; called by muse, mutect2, varscan2
- MDGA2 | c.1407A>G p.T469= (on ENST00000399232 / NM_001113498.2; = p.T171= on NM_182830.4) | Silent (SNP) | VAF 227/456 reads (50%) | catalogued as COSV100637274; called by muse, mutect2, varscan2
- MYO18A | c.4938G>A p.R1646= | Silent (SNP) | VAF 25/457 reads (5%) | catalogued as COSV100572049; called by muse, mutect2
- NALCN | c.4353C>A p.S1451= | Silent (SNP) | VAF 22/578 reads (4%) | catalogued as COSV99214500; called by muse, mutect2
- NELL1 | c.423T>A p.P141= | Silent (SNP) | VAF 20/548 reads (4%) | called by muse, mutect2
- NOTCH4 | c.5664G>A p.A1888= | Silent (SNP) | VAF 64/1166 reads (5%) | called by muse, mutect2
- OOSP1 | c.342G>A p.S114= | Silent (SNP) | VAF 91/275 reads (33%) | catalogued as rs545086371; called by muse, mutect2, varscan2
- OR10G2 | c.528C>A p.P176= | Silent (SNP) | VAF 42/572 reads (7%) | called by muse, mutect2
- OR4K2 | c.564T>G p.A188= | Silent (SNP) | VAF 178/523 reads (34%) | called by muse, mutect2, varscan2
- OR51M1 | c.195T>A p.P65= | Silent (SNP) | VAF 23/426 reads (5%) | called by muse, mutect2
- OTUD7A | c.804G>A p.E268= (on ENST00000307050 / NM_001382637.1; = p.E261= on NM_130901.3) | Silent (SNP) | VAF 24/700 reads (3%) | catalogued as rs1282770596; called by muse, mutect2
- PCLO | c.3996G>A p.V1332= | Silent (SNP) | VAF 17/533 reads (3%) | catalogued as COSV61667064; called by muse, mutect2
- PNPLA1 | c.1419C>T p.S473= (on ENST00000394571 / NM_001374623.1; = p.S378= on NM_173676.2) | Silent (SNP) | VAF 102/513 reads (20%) | catalogued as rs145988979; called by muse, mutect2, varscan2
- PRAMEF19 | c.903T>G p.T301= | Silent (SNP) | VAF 166/297 reads (56%) | called by muse, mutect2, varscan2
- PTPRN2 | c.1146G>A p.Q382= | Silent (SNP) | VAF 63/736 reads (9%) | called by muse, mutect2
- RCN2 | c.93G>T p.P31= | Silent (SNP) | VAF 123/675 reads (18%) | called by muse, mutect2, varscan2
- RIMS2 | c.1269T>G p.S423= (on ENST00000666250 / NM_001348490.2; = p.S231= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 88/516 reads (17%) | catalogued as COSV51651026, COSV51655287, COSV51702036; called by muse, mutect2, varscan2
- S1PR3 | c.759C>T p.I253= | Silent (SNP) | VAF 38/822 reads (5%) | catalogued as rs1395779426, COSV63980479; called by muse, mutect2
- SART1 | c.1887C>T p.D629= | Silent (SNP) | VAF 27/427 reads (6%) | catalogued as rs566033145; called by muse, mutect2
- SCARF2 | c.1290T>A p.T430= | Silent (SNP) | VAF 40/697 reads (6%) | called by muse, mutect2
- SIGLEC9 | c.168A>T p.V56= | Silent (SNP) | VAF 46/794 reads (6%) | called by muse, mutect2
- SLC24A2 | c.30T>G p.T10= | Silent (SNP) | VAF 17/429 reads (4%) | catalogued as COSV53856404; called by muse, mutect2
- SORL1 | c.4569C>T p.D1523= | Silent (SNP) | VAF 198/315 reads (63%) | catalogued as rs765220891, COSV52760273; called by muse, varscan2
- SUSD1 | c.570C>A p.I190= | Silent (SNP) | VAF 154/435 reads (35%) | catalogued as rs889595102; called by muse, mutect2, varscan2
- SYNGR3 | c.303C>A p.R101= | Silent (SNP) | VAF 42/538 reads (8%) | called by muse, mutect2
- TNK2 | c.366G>A p.G122= | Silent (SNP) | VAF 79/719 reads (11%) | catalogued as rs1225691066; called by muse, mutect2, varscan2
- TRIM28 | c.681C>T p.L227= | Silent (SNP) | VAF 490/731 reads (67%) | called by muse, mutect2, varscan2
- TRO | c.3000C>T p.G1000= | Silent (SNP) | VAF 282/282 reads (100%) | catalogued as rs771217762, COSV99435803; called by muse, mutect2, varscan2
- ZC3HAV1L | c.846G>A p.L282= | Silent (SNP) | VAF 370/728 reads (51%) | called by muse, mutect2, varscan2
- ZNF391 | c.435T>G p.S145= | Silent (SNP) | VAF 136/555 reads (25%) | called by muse, mutect2, varscan2
- ZNF714 | c.1407T>G p.T469= | Silent (SNP) | VAF 50/466 reads (11%) | called by muse, mutect2
- AL109984.1 | n.186+1096A>C | Intron (SNP) | VAF 26/886 reads (3%) | called by muse, mutect2
- APLP1 | c.148-44C>A | Intron (SNP) | VAF 92/1277 reads (7%) | called by muse, mutect2
- B3GAT2 | c.*909G>A | 3'UTR (SNP) | VAF 16/247 reads (6%) | called by muse, mutect2
- CYP2G1P | n.1165G>A | RNA (SNP) | VAF 20/755 reads (3%) | called by muse, mutect2
- GRIK3 | c.2565+49C>T | Intron (SNP) | VAF 118/379 reads (31%) | catalogued as rs369751433; called by muse, mutect2, varscan2
- KCNQ1 | c.1394-13505T>C | Intron (SNP) | VAF 133/217 reads (61%) | called by muse, mutect2, varscan2
- OTOF | c.*191G>A | 3'UTR (SNP) | VAF 17/389 reads (4%) | catalogued as rs894259720; called by muse, mutect2
- SCNN1B | c.-9+1582C>A | Intron (SNP) | VAF 31/330 reads (9%) | called by muse, mutect2
- Unknown | chr2:217713101 C>A | IGR (SNP) | VAF 23/399 reads (6%) | catalogued as COSV70403434; called by muse, mutect2
- ZNF366 | c.*1G>T | 3'UTR (SNP) | VAF 9/93 reads (10%) | catalogued as COSV59216749; called by muse, mutect2
